Somatic mutation profile of tumor specimen BA3108D (aliquot aq-BA3108D) from BEATAML1.0 case 2673, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,504 days).
Specimen BA3108D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c284fdb-7822-4410-a1e8-9414f543d670.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3314D (Solid Tissue Normal), aliquot aq-BA3314D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae81f5d6-b3d8-4f3f-8e3e-33f236ad8a96

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- U2AF1 | c.470A>C p.Q157P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs371246226, COSV52341120, COSV52341147; ClinVar: likely pathogenic / not provided; called by mutect2, varscan2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2, varscan2
- TSKS | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XIRP1 | c.2552C>G p.P851R | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- MYO15A | c.2544G>A p.S848= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
